Surgical pathology report (de-identified scan), TCGA case TCGA-FL-A1YF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii - Normal Study, specimen TCGA-FL-A1YF-11A (Solid Tissue Normal).

[page 1 of 2]
Surgical Pathology Report

Patient Name: [REDACTED] Accession #: [REDACTED]
Med Rec No: [REDACTED] Client: [REDACTED]
DOB: [REDACTED] Location: [REDACTED]
Gender: F Pt. Phone no [REDACTED]
Physician(s): [REDACTED] Reported: [REDACTED]
cc: [REDACTED]

History/Clinical Dx: Fibroids, endometriosis, pelvic pain

Postoperative Dx: Same, pending pathology examination

Specimen(s) Received:

Uterus, cervix, tubes and ovaries

ICD-0-3 Not applicable.
Normal from a non-cancer patient.
lw 11/11/11

DIAGNOSIS:

Uterus, cervix, tubes and ovaries:

Cervix:	Mild chronic inflammation
Endometrium:	Poorly developed secretory pattern
Myometrium:	Leiomyomata, intramural and submucosal
Right ovary:	Unremarkable
Right tube:	Unremarkable
Left ovary:	Unremarkable
Left tube:	Unremarkable

Gross Description

Received fresh labeled "uterus, cervix, bilateral tube and ovaries" is a previously opened uterus with attached cervix, separately submitted and unoriented tubes and ovaries. The entire specimen weighs 94.0 gms. The uterus measures 8.5 x 5.0 x 3.5 cm, the endometrium is tan to red, 0.2 cm in thickness and appears slightly hemorrhagic. The myometrium measures 2.0 cm in thickness and has three intramural leiomyomas ranging in size from 0.8 cm to 1.2 x 1.2 x 1.1 cm. The cervix measures 3.2 x 2.5 cm and grossly no lesion is identified at the cervical os. In the cervical canal there is a possible endocervical polyp measuring up to 1.7 cm. The tubes and ovaries are unoriented and both of the ovaries and tubes have tissue removed in the fresh state for

The ovaries and tubes are arbitrarily designated as A&B. The ovary A measures 3.7 x 2.5 x 2.0 cm, the cut section show a cyst filled with hemorrhagic fluid measuring 1.5 x 1.5 x 1.2 cm. The tube A measures 5.0 x 0.7 cm and grossly no lesions are identified. The ovary B measures 2.5 x 2.5 x 2.0 cm, the cut sections show a cyst with clotted blood measuring 1.0 x 0.8 x 0.6 cm. The tube B measures 2.0 x 0.7 cm, no gross lesions are identified. Representative sections are submitted.

Key to cassettes:

- | | | |
|---|---|---|
| 1 | - | Cervix with endocervical polyp |
| 2 | - | Full thickness endometrium and myometrium |
| 3 | - | Additional endometrium |
| 4 | - | Leiomyomas |
| 5 | - | Tube and ovary A |
| 6 | - | Tube and ovary B |

Regulatory Statement:

This laboratory statement may be applicable to some of the responsibilities listed in developing the above report. This test was developed and its performance characteristics determined by this laboratory. It is not intended for use in the diagnosis of disease or for other purposes for which it was not designed. The FDA has determined that such statement is appropriate. This test is used for clinical purposes. If an individual is reported as having a disease, it is the responsibility of the clinician to make an independent investigation of the diagnosis. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 2]
[REDACTED] **Surgical Pathology Report** [REDACTED]

Microscopic Description

The microscopic findings support the above diagnosis.

[REDACTED]

Source: NCI Genomic Data Commons file 05e2c8dc-2c4e-446a-96d2-633d618d2ad0 (TCGA-FL-A1YF.77548105-E280-4614-A76D-0177207D77D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).